Somatic mutation profile of tumor specimen 0DVPOL from CCDI case PBCMFT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 13.6 years (4,970 days).
Specimen 0DVPOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e3bca83-809a-421e-9d0b-d5edd520da41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfca3523-8de9-4053-82b7-000cada855bb

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 5, Silent 3, Nonsense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYOD1 | c.365T>G p.L122R | Missense Mutation (SNP) | VAF 237/238 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51452486; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 410/1047 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BOC | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 133/316 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs772475137, COSV56347972; called by muse, mutect2, varscan2
- FBN2 | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 294/693 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs139620380, COSV52509922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FIGN | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 169/670 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs748081011, COSV60763545; called by muse, mutect2, varscan2
- FRMPD4 | c.2641G>A p.V881M | Missense Mutation (SNP) | VAF 210/391 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs141220467, COSV66216755; called by muse, mutect2, varscan2
- IL2RG | c.1106C>G p.T369S | Missense Mutation (SNP) | VAF 99/335 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV52150027; called by muse, mutect2, varscan2
- NEB | c.18407C>T p.T6136M | Missense Mutation (SNP) | VAF 66/1465 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370108917; ClinVar: uncertain significance; called by muse, mutect2
- NLRP8 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 168/372 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372844411, COSV99406108; called by muse, mutect2, varscan2
- ROBO1 | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 605/665 reads (91%) | catalogued as rs1181501831, COSV71391612; called by muse, mutect2, varscan2
- TMEM132D | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 194/443 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs781773967, COSV70621040; called by muse, mutect2, varscan2
- C9orf40 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 249/534 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- CDH9 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 532/1273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CDS2 | c.666G>A p.M222I | Missense Mutation (SNP) | VAF 357/790 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DMPK | c.1321T>A p.S441T | Missense Mutation (SNP) | VAF 237/542 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLG1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 205/442 reads (46%) | called by muse, mutect2, varscan2
- IZUMO3 | c.518G>T p.R173L (on ENST00000543880 / NM_001365008.2; = p.R167L on NM_001271706.1) | Missense Mutation (SNP) | VAF 742/1606 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MAP3K4 | c.1010A>G p.Y337C | Missense Mutation (SNP) | VAF 308/707 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4Q3 | c.893T>G p.L298R | Missense Mutation (SNP) | VAF 30/1070 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SERPINB5 | c.328A>G p.R110G | Missense Mutation (SNP) | VAF 247/611 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- INTS6 | c.1341A>G p.G447= | Silent (SNP) | VAF 664/1524 reads (44%) | called by muse, mutect2, varscan2
- IQGAP1 | c.228C>T p.V76= | Silent (SNP) | VAF 271/634 reads (43%) | called by muse, mutect2, varscan2
- SLIT2 | c.430A>C p.R144= | Silent (SNP) | VAF 55/1880 reads (3%) | called by muse, mutect2
- ATM | c.-14T>G | 5'UTR (SNP) | VAF 210/538 reads (39%) | called by muse, mutect2, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 28/256 reads (11%) | called by muse, varscan2
- MCF2L | c.*72G>A | 3'UTR (SNP) | VAF 77/144 reads (53%) | catalogued as rs921821702; called by muse, mutect2, varscan2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55814242; called by muse, mutect2
- SUPT20H | c.1993-79G>T | Intron (SNP) | VAF 56/102 reads (55%) | called by muse, mutect2, varscan2
- ZNF268 | c.362-89C>T | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
